Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7302, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7302-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Surgical Pathology Report

[REDACTED]

[REDACTED]

Physician(s): [REDACTED]

Phy Locat [REDACTED]

=====

CLINICAL HISTORY

[REDACTED] woman presented with partial seizure, and has a left frontal mass with focal enhancement.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: Brain tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, site not specified, excisional biopsy: Oligodendroglioma.

B. Brain, site not specified, excisional biopsies [REDACTED]

Oligodendroglioma, focally anaplastic.

See Comment and Microscopy Description.

COMMENT

Part A is portions of cerebrum with an oligodendroglioma WHO grade II/IV.

The morphology of the neoplasm is consistent with a positive LOH tumor.

Part B contains tumor similar to that one in part B, but with a focal

area of anaplasia, i.e. an oligodendroglioma WHO grade III/IV.

Overall the neoplasm is a grade II oligodendroglioma, but it has a small

zone with anaplastic change

The morphological findings may be correlated with clinical, imaging, and

operative findings for their final interpretation and patient's follow up.

Electronically Signed Out

[REDACTED]

[REDACTED]

=====

PROCEDURES/ADDENDA

[page 2 of 3]
MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Submitted paraffin curls labeled dated [REDACTED]

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the AP Molecular Pathology laboratory as required by [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

=====

INTRA-OPERATIVE CONSULTATION

Brain tumor, biopsy, touch prep and smears: Glioma (C/W oligodendroglioma).

Part A. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

Received fresh, several fragments, 1.8-cm. in aggregate. Semi-firm, tannish-grey, glistening. In total, A1 and A2.

B.

Received from the Tumor Tissue Bank are 14 H-stained slides labeled

[REDACTED] from 1 to 7.

[REDACTED]

[page 3 of 3]
Senior Staff Pathologist

MICROSCOPIC DESCRIPTION

Part A.

Portions of cerebrum diffusely infiltrated by a neoplastic proliferation of uniform round nuclei with perinuclear haloes and slight pleomorphism.. The neoplasm infiltrates the cortex, with perinuclear satellitosis and intervening reactive astrocytes. The mitotic rate is about 2 mitoses/10 high power fields (40x). The vessels are focally prominent, but there is no microvascular cellular proliferation. There is no necrosis

Part B.

From the Tumor Tissue Bank, sections contain portions of cerebrum with a neoplasm similar to the one in part A. In this specimen, however, there is a focal area of tumor necrosis surrounded by neoplasm with microvascular cellular proliferation.

IMMUNOHISTOCHEMISTRY: The GFAP depicts a sparse gliofibrillary background.

About 20% of the cells over express the p53 protein. With the MIB-1 there is a proliferation index of about 12% in the more active areas.

ICD-9(s):

191.1 191.1

Histo Data

Part A: Brain tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
mGFAP-DA x 1	1		
H/E x 1	1		
MIB1-DA x 1	1		
P53DO7 x 1	1		
H/E x 1	2		

*** End of Report ***

Source: NCI Genomic Data Commons file 8e0e3019-90a8-4a07-9354-7588780af358 (TCGA-DU-7302.AD715B7B-52A2-493A-99D2-B5EC2B18A709.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).